Somatic mutation profile of tumor specimen TCGA-AB-2921-03A (aliquot TCGA-AB-2921-03A-01W-0755-09) from TCGA case TCGA-AB-2921, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.0 years (20,454 days).
Specimen TCGA-AB-2921-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f77e9b8-b58c-4171-8c3e-e53817afd10b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2921-11A (Solid Tissue Normal), aliquot TCGA-AB-2921-11A-01W-0755-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e49bac3b-4838-4257-98db-269f8489b3d6

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EHD2 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774957397, COSV99621673; called by muse, mutect2, varscan2
- PLA2G2D | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs756989161, COSV100907999, COSV64281689; called by muse, mutect2, varscan2
- NFE2 | c.814delinsGGGCAA p.R272Gfs*32 | Frame Shift Ins (INS) | VAF 24/102 reads (24%) | called by pindel, varscan2*
